Somatic mutation profile of tumor specimen MP2PRT-PARRHC-TMP1-A (aliquot MP2PRT-PARRHC-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARRHC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,200 days).
Specimen MP2PRT-PARRHC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2004130-9241-445e-bcb5-df658799150e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRHC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRHC-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb9922e-e476-448b-ae15-117cce9feb49

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, In Frame Ins 2, Silent 2, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN5 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 281/448 reads (63%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs782566817; called by muse, mutect2, varscan2
- COL4A1 | c.2377G>A p.V793M | Missense Mutation (SNP) | VAF 208/345 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs769302846; called by muse, mutect2, varscan2
- CPB1 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 21/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51573104; called by muse, mutect2
- CYP19A1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 121/429 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202076619, COSV53059469; called by muse, mutect2, varscan2
- FRK | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 143/267 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs190975105; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 170/627 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV56241008; called by muse, mutect2, varscan2
- WASHC2C | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 51/388 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs781911163; called by muse, mutect2, varscan2
- ZBTB8B | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 96/519 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1284559086; called by muse, mutect2, varscan2
- CHCHD2 | c.266_267insGGGGCGAAGCCGGGCGGAA p.N89Kfs*9 | Frame Shift Ins (INS) | VAF 38/379 reads (10%) | called by mutect2, pindel
- EN1 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IGHV3-48 | c.352_353insGGA | In Frame Ins (INS) | VAF 105/119 reads (88%) | called by mutect2, pindel*, varscan2*
- MYH13 | c.1688del p.N563Tfs*41 | Frame Shift Del (DEL) | VAF 233/609 reads (38%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PSME4 | c.5315C>G p.S1772C | Missense Mutation (SNP) | VAF 16/437 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBMXL3 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 150/703 reads (21%) | called by muse, mutect2, varscan2
- VPS13A | c.3335A>G p.K1112R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZFAT | c.2208_2209insCTCCCTTCCCCGGCG p.R736_K737insLPSPA | In Frame Ins (INS) | VAF 65/321 reads (20%) | called by mutect2, pindel, varscan2
- TCERG1L | c.423C>G p.L141= | Silent (SNP) | VAF 84/529 reads (16%) | called by muse, mutect2, varscan2
- TGM1 | c.1707G>T p.V569= | Silent (SNP) | VAF 257/558 reads (46%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3769C>G | Intron (SNP) | VAF 189/501 reads (38%) | called by muse, mutect2, varscan2
